Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A66Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A66Y-01A (Primary Tumor).

TSS Patient ID:

OpenClinica ID:

Surgical Date:

Gross Description: Tumor are located in sulobes 5,7 and 8, composed of many masses, with 6x4x4cm in maximun size, moderate-margins, solid and firm, gray-white in cutting section.

Microscopic Description: Tumor cells form the trabecular patterns conecting each other, or nodules or sheets patterns intervening in begnin tissue. Tumor invades into fibrous stroma. The tumor cells retain apolygonal shape and have round vesicular nuclei with prominent nucleoli. The amount of cytoplasm are abundant and the cytoplasm is basophilic or clear. Nuclei are irregularly large and hyperchromatic with prominent nucleoli. Mitoses are present. Stroma is marked fibrous and hyaline.

Diagnosis Details: Hepatocellular carcinoma, poorly-differentiated

Comments:

Formatted Path Reports: LIVER TISSUE CHECKLIST

Specimen type: Wedge resection, lobectomy

Tumor size: 6 x 4 x 4 cm

Focality: Not specified

Histologic type: Hepatocellular carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3 NOS
Carcinoma, hepatocellular 8170/3
Site: Liver C22.0
JED 5/16/13

Source: NCI Genomic Data Commons file 5096532f-225e-4213-b66e-749065f80245 (TCGA-ED-A66Y.14F29317-F7B9-49D4-B215-EF489A4283CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).